Somatic mutation profile of tumor specimen TARGET-30-PANWRR-01A (aliquot TARGET-30-PANWRR-01A-01D) from TARGET case TARGET-30-PANWRR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 8.0 years (2,937 days).
Specimen TARGET-30-PANWRR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c596047b-63c3-4783-b2f2-ea2672c0ce65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANWRR-10A (Blood Derived Normal), aliquot TARGET-30-PANWRR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/539d032e-e55e-4526-ac21-90ac7ab8ec3e

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- AGO4 | c.1703A>C p.N568T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.119); catalogued as COSV64618903; called by muse, mutect2, varscan2
- CC2D1A | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.359); catalogued as rs183492797, COSV58781490; called by muse, mutect2, varscan2
- DCAF15 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54333932; called by muse, mutect2, varscan2
- KCNA4 | c.1913C>A p.T638K | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.05); catalogued as COSV60254993, COSV60256317; called by muse, mutect2, varscan2
- NBEAL2 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52763326; called by muse, mutect2, varscan2
- PLA2G4F | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV51829769; called by muse, mutect2, varscan2
- PPDPFL | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs1327256996, COSV57460875, COSV57460969; called by muse, mutect2, varscan2
- VPS18 | c.1916T>C p.V639A | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55032443; called by muse, mutect2, varscan2
- ZFC3H1 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV66431945, COSV66432878; called by muse, varscan2
- CDKN1C | c.337del p.V113Wfs*159 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel
- C9orf152 | c.189A>G p.P63= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as COSV68762734, COSV68763202; called by muse, mutect2, varscan2
